Gene-level copy-number profile of tumor specimen TCGA-44-2662-01B from TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-44-2662-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cedd3b95-6d53-48b8-a249-ae427cc13183.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-2662-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/de254452-7a16-45d9-b541-1286795dcf62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,403; copy number 2: 57,671; copy number 3: 197; copy number 5: 2.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-2662-01A-01D-A273-01): tumor purity 0.26, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:33,437,363–33,454,453, 1 gene, copy number 5 (within-gene range 2–5): SYNGAP1-AS1.
- chr6:33,453,970–33,457,544, 1 gene, copy number 5: ZBTB9.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
